Gene-level copy-number profile of tumor specimen TCGA-A5-A0GR-01A from TCGA case TCGA-A5-A0GR, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G2; Age at diagnosis: 69.4 years (25,353 days).
Specimen TCGA-A5-A0GR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.7b0a6186-9413-4936-8256-34c49be49893.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A5-A0GR-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5e458df4-e3f3-4075-8921-bfd11a8dffef

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 14,647; copy number 2: 40,517; copy number 3: 2,691; copy number 4: 473; copy number 5: 1,488.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A5-A0GR-01A-11D-A120-01): tumor purity 0.5, ploidy 1.82, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,488 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:134,313,576–198,222,513, 1,105 genes, copy number 5 (broad region; genes not listed).
- chr6:11,173,452–11,382,348, 3 genes, copy number 5 (within-gene range 3–5): AL139807.1, NEDD9, AL022098.1.
- chr6:11,417,207–11,481,324, 1 gene, copy number 5 (within-gene range 3–5): AL445430.1.
- chr8:102,125,432–102,238,961, 3 genes, copy number 5 (within-gene range 2–5): MIR5680, AP001328.1, RRM2B.
- chr18:47,390–15,330,282, 376 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 14,647. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
